Somatic mutation profile of tumor specimen 0DSI9H from CCDI case PBCIBF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 9.2 years (3,372 days).
Specimen 0DSI9H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b682394-4094-4133-9572-f3efc68653d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI86 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbbe12e2-be39-4b7c-af32-febb74ef6368

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TNPO2 | c.2392C>T p.Q798* (on ENST00000425528 / NM_001382240.1; = p.Q788* on NM_013433.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 332/585 reads (57%) | called by muse, varscan2
- NOS1AP | c.1101C>T p.N367= | Silent (SNP) | VAF 190/467 reads (41%) | catalogued as rs776920540, COSV62631849; called by muse, varscan2
